Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4769, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4769-01A (Primary Tumor).

[page 1 of 2]
...

Clinical Diagnosis & History:

with exophytic 3 cm left renal mass.

Specimens Submitted:

1: KIDNEY, LEFT, PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY, LEFT, PARTIAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
A second renal cell carcinoma, papillary type, is present

Fuhrman Nuclear Grade:

The clear cell carcinoma is nuclear grade II/IV. The papillary tumor is type I

Tumor Size:

Greatest diameter is 2.2 cm.
The size of the papillary tumor is 1.1 cm

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

2 minute so called "papillary tubular adenomas" are present

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section consultation labeled, "Left renal tumor with satellite tumors, stitch marks the margin", and consists of a partial nephrectomy specimen measuring 5.0 x 3.5 x 1.0 cm. The attached yellow tan fatty tissue measures up to 5 cm in thickness. The margin with a stitch is inked blue. Cut section of the specimen shows a well-circumscribed gray tan lobulated tumor nodule with focal hemorrhagic areas measuring 2.2 x 2.0 x 2.0 cm. It is grossly located 0.2 cm from the resection margin. This is designated as tumor number 1. Tumor number two shows a light tan friable necrotic appearance and measures 1.1 x 1.1 x 0.9 cm, is located 0.3 cm from the resection margin. Tumor number one grossly abuts the renal capsule, but does not involve it or extend into the perinephric fat. The remainder of the kidney parenchyma is red tan and grossly unremarkable. A representative section of the larger nodule is frozen. A sample of tumor and normal kidney is given to TPS. Representative sections are submitted.

Summary of sections:

FSC -- frozen section control

T1 -- tumor number one

T2 -- tumor number two

Summary of Sections:

Part 1: KIDNEY, LEFT, PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	fsc	1
5	t2	5

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL TUMOR MARGINS ARE NEGATIVE FOR TUMOR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 7498e0e1-8eb1-40c5-b03b-4d5625f185cf (TCGA-BP-4769.51E88617-D149-4C68-BCCC-589274E4F342.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).